Somatic mutation profile of tumor specimen TCGA-BP-4974-01A (aliquot TCGA-BP-4974-01A-01D-1462-08) from TCGA case TCGA-BP-4974, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 58.3 years (21,310 days).
Specimen TCGA-BP-4974-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b7e4f51-03fd-460b-ad27-4f382d3871b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4974-11A (Solid Tissue Normal), aliquot TCGA-BP-4974-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95e1f828-a9c6-4dd2-a51f-0b4df22086ac

The open-access MAF lists 36 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 23, Silent 6, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP2 | c.1496A>C p.K499T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV58754236; called by muse, mutect2, varscan2
- ANKS1B | c.3115G>A p.A1039T (on ENST00000547776 / NM_152788.4; = p.A205T on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59122747; called by muse, mutect2, varscan2
- CDAN1 | c.2921G>C p.C974S | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62333402; called by muse, mutect2
- CEP57L1 | c.1355G>T p.R452I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV100425660, COSV61245545; called by muse, mutect2
- CRELD1 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV55978108; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1135G>A p.G379R (on ENST00000361735 / NM_015935.5; = p.G293R on NM_014955.3) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV62283601; called by muse, mutect2, varscan2
- FAM76A | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1215403399, COSV50549538; called by muse, mutect2, varscan2
- GABRR1 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65620091; called by muse, mutect2, varscan2
- HEATR1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63979515; called by muse, mutect2, varscan2
- LMAN2 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV57425333; called by muse, mutect2
- MAP3K5 | c.1759T>G p.S587A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV62890904; called by muse, mutect2, varscan2
- MARK1 | c.2128A>G p.S710G | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65069874; called by muse, varscan2
- NUP160 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV65855254; called by muse, mutect2
- PKHD1L1 | c.1086T>A p.N362K | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV65748787; called by muse, mutect2, varscan2
- POLA1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.524); catalogued as COSV66889185; called by muse, mutect2, varscan2
- PRKDC | c.6731G>A p.C2244Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58046682, COSV58054285; called by muse, mutect2, varscan2
- REG3G | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55450820; called by muse, mutect2, varscan2
- RFPL1 | c.76del p.L26Wfs*22 | Frame Shift Del (DEL) | VAF 19/138 reads (14%) | catalogued as COSV100585833, COSV62978649; called by mutect2, pindel, varscan2
- RYR3 | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV66802292; called by muse, mutect2, varscan2
- SLC11A1 | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs777180010, COSV51918421, COSV99262476; called by muse, mutect2, varscan2
- UCP1 | c.622T>A p.L208I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV53768300; called by muse, mutect2, varscan2
- ZNF320 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV67088629; called by muse, varscan2
- ZNF320 | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV67088633; called by muse, varscan2
- ZNF341 | c.2369G>A p.G790D (on ENST00000375200 / NM_001282935.1; = p.G783D on NM_032819.4) | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.062); catalogued as COSV61010353; called by muse, mutect2
- DHX58 | c.687_695del p.F229_D231del | In Frame Del (DEL) | VAF 8/100 reads (8%) | called by mutect2, pindel
- HNRNPUL2 | c.1803dup p.C602Mfs*6 | Frame Shift Ins (INS) | VAF 11/82 reads (13%) | called by mutect2, pindel
- LARGE2 | c.1275_1277del p.P427del | In Frame Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- SFXN1 | c.769_770dup p.L257Ffs*2 | Frame Shift Ins (INS) | VAF 30/272 reads (11%) | called by pindel, varscan2
- SUPT4H1 | c.106del p.C36Vfs*7 | Frame Shift Del (DEL) | VAF 31/264 reads (12%) | called by mutect2, pindel, varscan2
- WASHC4 | c.2225_2226del p.T742Sfs*5 | Frame Shift Del (DEL) | VAF 23/189 reads (12%) | called by mutect2, pindel, varscan2
- EEF1AKNMT | c.561C>T p.A187= (on ENST00000361735 / NM_015935.5; = p.A101= on NM_014955.3) | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV62283596; called by muse, mutect2, varscan2
- KLHL8 | c.471T>C p.C157= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV56748838; called by muse, mutect2, varscan2
- LRFN5 | c.1080C>A p.S360= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV53268417; called by muse, mutect2
- MED1 | c.2595C>T p.F865= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as rs1263167056, COSV56125769; called by muse, mutect2, varscan2
- SCG2 | c.381T>A p.S127= | Silent (SNP) | VAF 26/425 reads (6%) | catalogued as COSV59541174; called by muse, mutect2
- YEATS4 | c.66T>G p.V22= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV56089405; called by muse, mutect2
